TCGA case TCGA-34-5241 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6013a4fd-89cf-48a7-a465-c7b644afb4a5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 79 years; Vital status: Dead; Days to death: 515 days (1.4 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 79.7 years (29,098 days); Year of diagnosis: 2009; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 515 days (1.4 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 428 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 515 days (1.4 years); Disease response: Tumor Free.

Molecular and laboratory tests
- KRAS mutation, nos: Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 25; Tobacco smoking onset year: 1954; Tobacco smoking quit year: 1979.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-34-5241-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-34-5241-01A-01-BS1: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 70; Percent normal cells: 30; Percent necrosis: 15; Percent stromal cells: 10.
  Slide TCGA-34-5241-01A-01-TS1: Section location: Top; Percent tumor cells: 57; Percent tumor nuclei: 75; Percent normal cells: 3; Percent necrosis: 25; Percent stromal cells: 15.
- Sample TCGA-34-5241-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-34-5241-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Lower; KRAS mutation found: No; KRAS gene analysis indicator: No; Eml4 alk translocation status: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: No; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 515 days; disease-specific survival: no event (censored), 515 days; progression-free interval: no event (censored), 515 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-34-5241-01A-01D-1439-01): tumor purity 0.88, ploidy 3.75, whole-genome doublings 1.
